Somatic mutation profile of tumor specimen 4cdeecb5-19fb-493c-91f5-eb0efc (aliquot 4cdeecb5-19fb-493c-91f5-eb0efc_D6) from CPTAC case 11CO030, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 4cdeecb5-19fb-493c-91f5-eb0efc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 302e9050-ce40-4036-8f91-fc2dad337fae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7dc8c605-b0a0-4491-a2f2-ef457c (Blood Derived Normal), aliquot 7dc8c605-b0a0-4491-a2f2-ef457c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98110af3-7214-45bc-ace1-9797687b48f1

The open-access MAF lists 86 somatic variants for this specimen: 55 protein-altering or splice-affecting, 23 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 23, Nonsense Mutation 9, Intron 6, Splice Region 2, Splice Site 1, Nonstop Mutation 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3980C>G p.S1327* | Nonsense Mutation (SNP) | VAF 187/387 reads (48%) | catalogued as rs1554085429, COSV57323640, COSV57335489, COSV57371230; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 133/412 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APLF | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1281800302; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 108/491 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368301208, COSV100023748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHODL | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202176979, COSV54731563; called by muse, mutect2, varscan2
- CNOT2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1240355211; called by muse, mutect2, varscan2
- COG4 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 229/443 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs747240944; called by muse, mutect2, varscan2
- COL14A1 | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs370064596; called by muse, mutect2, varscan2
- COL5A3 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as rs763735614, COSV53418484; called by muse, mutect2, varscan2
- EPG5 | c.6521C>T p.P2174L | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs775158816, COSV56351878; called by muse, mutect2, varscan2
- GALNT17 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 113/245 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs771622041, COSV61146904; called by muse, mutect2, varscan2
- HHIPL1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs544154355, COSV58090818; called by muse, mutect2, varscan2
- HIBADH | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55315472; called by muse, mutect2, varscan2
- HR | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 26/215 reads (12%) | catalogued as rs1207891536; called by muse, mutect2, varscan2
- HTR1D | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.426); catalogued as rs779362864, COSV58448057; called by muse, mutect2, varscan2
- IRX4 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1372444611; called by muse, mutect2, varscan2
- KCNH8 | c.2836C>T p.Q946* | Nonsense Mutation (SNP) | VAF 129/516 reads (25%) | catalogued as COSV60469644; called by muse, mutect2, varscan2
- NCAM2 | c.1878C>A p.Y626* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV99525878; called by muse, mutect2
- NRG1 | c.399C>T p.N133= | Splice Region (SNP) | VAF 39/123 reads (32%) | catalogued as rs374418193, COSV55171785; called by muse, mutect2, varscan2
- NUTM2B | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 64/876 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs1238966175; called by muse, mutect2
- OAZ3 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs762424853; called by muse, mutect2, varscan2
- PCBP1 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA7 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100971868; called by muse, mutect2, varscan2
- PCDHAC1 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1554206828, COSV53836704; called by muse, varscan2
- PEG3 | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV55637352; called by muse, mutect2, varscan2
- POM121C | c.2657C>T p.T886M (on ENST00000607367; = p.T644M on NM_001099415.3) | Missense Mutation (SNP) | VAF 51/824 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as rs1395295825; called by muse, mutect2
- RADIL | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs747080978, COSV68202124; called by muse, mutect2, varscan2
- TLN2 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV60896827; called by muse, mutect2, varscan2
- VAV1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs771269172, COSV58378743; called by muse, mutect2, varscan2
- ZAP70 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as CM994076; called by muse, mutect2, varscan2
- ZSCAN10 | c.1432C>T p.R478C (on ENST00000252463; = p.R533C on NM_032805.3) | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99373748; called by muse, mutect2
- AMY1C | c.897G>C p.W299C | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APC | c.5383T>C p.S1795P | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRF1 | c.1003A>C p.S335R | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CDCA7L | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COL1A1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSE | c.1517G>A p.C506Y | Missense Mutation (SNP) | VAF 59/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FGF14 | c.395A>C p.Y132S | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- IGF2R | c.2055T>G p.D685E | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- KAT14 | c.2263G>T p.E755* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- KLHL4 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 59/334 reads (18%) | called by muse, mutect2, varscan2
- KPNA4 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRK1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MAGI2 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPAT | c.3515G>T p.C1172F | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- NUDT8 | c.711A>G p.*237Wext*? | Nonstop Mutation (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- PADI2 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PCNX2 | c.5205G>A p.W1735* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNNI3K | c.2368T>C p.S790P | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSSK2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by mutect2, varscan2
- TTC16 | c.1853-2A>C p.X618_splice | Splice Site (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- UNC45A | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ZNF354A | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- ZNF717 | c.186G>A p.G62= | Splice Region (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- ANKRD24 | c.1746G>A p.T582= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs745460145, COSV99516744; called by muse, mutect2, varscan2
- ARHGEF1 | c.765G>A p.S255= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs782763644, COSV61528623; called by muse, mutect2, varscan2
- BCL6 | c.294G>T p.R98= | Silent (SNP) | VAF 77/511 reads (15%) | catalogued as COSV51654633; called by muse, mutect2, varscan2
- CLEC14A | c.945G>A p.P315= | Silent (SNP) | VAF 196/352 reads (56%) | catalogued as rs776977655; called by muse, mutect2, varscan2
- CORO1A | c.162C>T p.S54= | Silent (SNP) | VAF 141/278 reads (51%) | catalogued as rs536390638, COSV54631117; called by muse, mutect2, varscan2
- DKC1 | c.744G>A p.R248= | Silent (SNP) | VAF 117/509 reads (23%) | called by muse, mutect2, varscan2
- FAM207A | c.264C>T p.S88= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as rs771913102, COSV52422431; called by muse, mutect2, varscan2
- GUCY1A1 | c.1227G>A p.L409= | Silent (SNP) | VAF 110/454 reads (24%) | catalogued as COSV56654901; called by muse, mutect2, varscan2
- HELZ | c.4830A>C p.V1610= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- HTR1A | c.666G>A p.A222= | Silent (SNP) | VAF 218/793 reads (27%) | catalogued as COSV60500938, COSV60502320; called by muse, mutect2, varscan2
- KLHDC10 | c.351G>A p.S117= | Silent (SNP) | VAF 156/370 reads (42%) | catalogued as rs756875729; called by muse, mutect2, varscan2
- LARGE1 | c.45G>A p.S15= | Silent (SNP) | VAF 46/304 reads (15%) | catalogued as rs752560976, COSV100505469; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR4S1 | c.882T>C p.N294= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- OR6B2 | c.726C>T p.A242= | Silent (SNP) | VAF 77/259 reads (30%) | catalogued as rs1477066094; called by muse, mutect2, varscan2
- PAK5 | c.591C>T p.A197= | Silent (SNP) | VAF 126/527 reads (24%) | catalogued as rs767126500; called by muse, mutect2, varscan2
- PCDHB8 | c.2082G>A p.A694= | Silent (SNP) | VAF 30/556 reads (5%) | catalogued as rs1554281580, COSV50804973; called by muse, mutect2
- PDCD11 | c.2259C>T p.S753= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs762635887; called by muse, mutect2, varscan2
- SON | c.5208G>A p.P1736= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs760341788, COSV51657884; called by muse, mutect2, varscan2
- TCL1A | c.105G>T p.L35= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- TSPAN33 | c.306C>T p.T102= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs761207005, COSV99179762; called by muse, mutect2, varscan2
- UNC79 | c.393C>T p.Y131= | Silent (SNP) | VAF 130/249 reads (52%) | catalogued as rs1172510316; called by muse, mutect2, varscan2
- VEPH1 | c.2364C>T p.F788= | Silent (SNP) | VAF 152/294 reads (52%) | catalogued as rs527392367, COSV62876749; called by muse, varscan2
- ZNF772 | c.1338A>G p.K446= | Silent (SNP) | VAF 15/232 reads (6%) | called by muse, mutect2
- AC024940.1 | n.4186T>C | RNA (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.130-33994G>A | Intron (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- DYSF | c.2926-12T>G | Intron (SNP) | VAF 84/327 reads (26%) | called by mutect2, varscan2
- MAGI2 | c.538+43674G>A | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as rs867299806; called by muse, varscan2
- MED19 | c.571+110_571+111dup | Intron (INS) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- MGAT2 | c.*1A>G | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- RGPD1 | c.48+5888G>A | Intron (SNP) | VAF 54/161 reads (34%) | catalogued as rs758068458; called by muse, mutect2, varscan2
- TUBB8 | c.166+11C>T | Intron (SNP) | VAF 141/525 reads (27%) | catalogued as rs368865511; called by muse, mutect2, varscan2
